Somatic mutation profile of tumor specimen TCGA-A5-AB3J-01A (aliquot TCGA-A5-AB3J-01A-11D-A403-09) from TCGA case TCGA-A5-AB3J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.1 years (19,020 days).
Specimen TCGA-A5-AB3J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36683c82-c764-4d65-8c97-66e44632f764.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-AB3J-10A (Blood Derived Normal), aliquot TCGA-A5-AB3J-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a504d466-6db6-4058-8eb2-52377487b5bd

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 2, RNA 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- ESR1 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52781024; called by muse, mutect2, varscan2
- ACTL9 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782170839, COSV100185424; called by muse, mutect2
- BIRC2 | c.256T>A p.C86S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99926755; called by muse, mutect2, varscan2
- CMA1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs200452938, COSV51625615; called by mutect2, varscan2
- COL4A4 | c.4724C>T p.A1575V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs199760323, COSV61630167; called by muse, mutect2, varscan2
- CRB2 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs373758779; called by muse, varscan2
- DDX3X | c.1214G>T p.G405V (on ENST00000399959; = p.G406V on NM_001356.5) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101302470; called by muse, mutect2
- DMPK | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.111); catalogued as COSV99353359; called by muse, mutect2, varscan2
- F2 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV61315325, COSV61317795; called by mutect2, varscan2
- FBRS | c.565G>A p.G189R (on ENST00000287468; = p.G709R on NM_001105079.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs778326728, COSV99789189; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58548790; called by mutect2, varscan2
- GCK | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.98); catalogued as COSV100357268; called by muse, mutect2, varscan2
- IRF4 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs781586995, COSV66705021, COSV66706054; called by muse, mutect2, varscan2
- JPH3 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.183); catalogued as COSV52467564; called by muse, mutect2, varscan2
- KCNK2 | c.310T>A p.S104T (on ENST00000444842 / NM_001017425.3; = p.S89T on NM_014217.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101221762; called by muse, mutect2, varscan2
- MET | c.2650A>G p.N884D | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV100577274; called by muse, mutect2
- MLPH | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99222356; called by muse, mutect2, varscan2
- MORC4 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99717342; called by muse, mutect2, varscan2
- PEX5L | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99829180; called by muse, mutect2, varscan2
- POLE | c.2969T>G p.F990C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100267271; called by muse, mutect2, varscan2
- RUNX1T1 | c.1763C>T p.P588L (on ENST00000265814 / NM_001198628.1; = p.P561L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs147343453, COSV56137322; called by muse, mutect2, varscan2
- SMCR8 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs778384203, COSV100329182; called by muse, varscan2
- SPEG | c.5533G>A p.A1845T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); catalogued as rs759067349, COSV56675331; called by muse, mutect2, varscan2
- SPTBN1 | c.6592G>T p.A2198S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs780273707, COSV100442899; called by muse, mutect2, varscan2
- SPTBN1 | c.6593C>T p.A2198V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV100442901; called by muse, mutect2, varscan2
- STAC | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs149366291, COSV99830252; called by muse, mutect2
- SUCLG2 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100214470; called by muse, mutect2, varscan2
- SYNE2 | c.8997G>T p.L2999F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.445); catalogued as rs773684701, COSV100648009; called by mutect2, varscan2
- TMEM132D | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764438255, COSV70594541, COSV70604549; called by muse, mutect2, varscan2
- YME1L1 | c.946+1G>C p.X316_splice (on ENST00000326799 / NM_139312.3; = p.X259_splice on NM_014263.4) | Splice Site (SNP) | VAF 17/149 reads (11%) | catalogued as COSV100463854; called by muse, mutect2, varscan2
- ZMYM2 | c.2617C>T p.Q873* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV101243901; called by muse, mutect2, varscan2
- CBR4 | c.26_32delinsAG p.G9Efs*35 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by pindel, varscan2*
- MUC5B | c.7182dup p.K2395Efs*9 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- TK1 | c.508_510del p.K170del | In Frame Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- AKAP12 | c.1689C>T p.G563= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs750541234, COSV53574708; called by mutect2, varscan2
- DBF4 | c.60C>T p.V20= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as COSV99719398; called by muse, mutect2
- DMPK | c.1542G>A p.E514= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99353361; called by muse, mutect2, varscan2
- GRXCR1 | c.501C>T p.R167= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV101295706; called by muse, mutect2, varscan2
- LRP2 | c.96T>C p.H32= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99789231; called by muse, mutect2, varscan2
- PLEKHM3 | c.1497G>A p.T499= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs369516191; called by muse, varscan2
- PPP1R3A | c.2052C>T p.D684= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs779836256, COSV52891134; called by muse, mutect2, varscan2
- PRKCQ | c.1257C>T p.D419= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs746114853, COSV99577227; called by mutect2, varscan2
- STXBP2 | c.1278C>A p.I426= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99657244; called by muse, mutect2, varscan2
- WNT3 | c.831C>T p.Y277= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs903602434, COSV56644165; called by muse, mutect2, varscan2
- F9 | c.-1del | 5'UTR (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- SNORD115-33 | n.33_42del | RNA (DEL) | VAF 13/76 reads (17%) | called by pindel, varscan2
- STAG3L4 | n.410G>T | RNA (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
